Somatic mutation profile of tumor specimen TARGET-20-PARNFR-03A (aliquot TARGET-20-PARNFR-03A-01D) from TARGET case TARGET-20-PARNFR, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.1 years (6,261 days).
Specimen TARGET-20-PARNFR-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95f92920-1e1a-491c-9684-61a95263fb64.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARNFR-14A (Bone Marrow Normal), aliquot TARGET-20-PARNFR-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecfe9f1d-3930-4b02-ab1d-1f1c815033e4

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, 3'UTR 6, Silent 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF3 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 108/195 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs370600463, COSV99293934; called by muse, mutect2, varscan2
- CUL9 | c.4916C>T p.T1639I | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.349); catalogued as rs772062849; called by muse, mutect2, varscan2
- DNAH2 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200520443; called by muse, mutect2, varscan2
- FAT1 | c.9578C>A p.A3193E | Missense Mutation (SNP) | VAF 86/196 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.872); catalogued as rs1173123959, COSV71672379; called by muse, mutect2, varscan2
- MET | c.3218C>T p.P1073L | Missense Mutation (SNP) | VAF 72/132 reads (55%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.563); catalogued as rs370529693; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SIGLEC12 | c.1439G>A p.G480E (on ENST00000291707 / NM_053003.4; = p.G362E on NM_033329.2) | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs749781933; called by muse, varscan2
- TAF1L | c.2864G>A p.R955K | Missense Mutation (SNP) | VAF 140/274 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs145015801; called by muse, mutect2, varscan2
- TRRAP | c.6235C>T p.P2079S (on ENST00000359863 / NM_001244580.1; = p.P2061S on NM_003496.3) | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs369775505; called by muse, mutect2, varscan2
- ACOT4 | c.564_569delinsTCAAAG p.A189_Y190delinsQS | Missense Mutation (ONP) | VAF 47/130 reads (36%) | called by pindel, varscan2*
- MACF1 | c.18525A>G p.E6175= (on ENST00000372915; = p.E4220= on NM_012090.5) | Silent (SNP) | VAF 85/190 reads (45%) | catalogued as rs754144854; called by muse, mutect2, varscan2
- ARID1B | c.3511+485C>G | Intron (SNP) | VAF 80/190 reads (42%) | called by muse, mutect2, varscan2
- ARID2 | c.*958A>C | 3'UTR (SNP) | VAF 79/180 reads (44%) | called by muse, mutect2, varscan2
- ATXN1 | c.*5228_*5231delinsA | 3'UTR (DEL) | VAF 54/153 reads (35%) | catalogued as rs1313826922; called by pindel, varscan2*
- CPM | c.*260A>G | 3'UTR (SNP) | VAF 114/212 reads (54%) | called by muse, mutect2, varscan2
- DICER1 | c.*2645G>A | 3'UTR (SNP) | VAF 97/208 reads (47%) | catalogued as rs1162530452; called by muse, mutect2, varscan2
- HDAC4 | c.*4785T>C | 3'UTR (SNP) | VAF 86/171 reads (50%) | catalogued as rs1051313801; called by muse, varscan2
- PTPN11 | c.*597del | 3'UTR (DEL) | VAF 65/168 reads (39%) | called by mutect2, pindel, varscan2
- TAF8 | chr6:42048662 ins T | 5'Flank (INS) | VAF 27/71 reads (38%) | catalogued as rs779766268; called by mutect2, pindel, varscan2
